Gene-level copy-number profile of tumor specimen TCGA-CR-7402-01A from TCGA case TCGA-CR-7402, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 68.8 years (25,138 days).
Specimen TCGA-CR-7402-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.77a224f3-b393-4067-9a35-510bb2bb8a38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-7402-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7c5bc1a-4a7a-4c60-99e5-a7ff77d133e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 11,266; copy number 2: 41,855; copy number 3: 2,363; copy number 4: 1,949; copy number 5: 1,996; copy number 9: 376.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7402-01A-11D-2010-01): tumor purity 0.61, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:191,017,954–191,174,835, 7 genes: AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,372 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–168,924,590, 1,209 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:172,039,578–176,867,838, 49 genes, copy number 5 (within-gene range 4–5): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1, NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209.
- chr3:187,291,272–192,917,856, 62 genes, copy number 5 (broad region; genes not listed).
- chr6:45,573,346–58,438,364, 196 genes, copy number 5 (broad region; genes not listed).
- chr9:84,275,457–110,172,512, 478 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr16:6,037,210–6,092,954, 2 genes, copy number 5: AC009135.2, AC009135.1.
- chr18:47,390–15,330,282, 376 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,883. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
